FM case AD1971 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/4e0d9e6c-1fbe-4ff8-8bb6-aea931df3829

Female, 54.1 years: Clear cell carcinoma (ICD-O-3 8310/3) of the ovary; primary biopsied or resected from the ovary. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
